Gene-level copy-number profile of tumor specimen TCGA-EJ-5531-01A from TCGA case TCGA-EJ-5531, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.3 years (22,760 days).
Specimen TCGA-EJ-5531-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.fb189fe4-223b-4cca-969a-edf60a08f816.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-5531-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c4c1e390-de10-4fb4-818d-eb13bc8e4bcc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 5,690; copy number 2: 51,632; copy number 3: 2,439.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-5531-01A-01D-1574-01): tumor purity 0.26, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:98,338,744–100,903,282, 46 genes: AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1, AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2, CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P, AC113385.3, AC113385.2, AC113385.1, AC021086.1, FAM174A, AC027315.1, RN7SKP62, ST8SIA4, MIR548P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,322. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
